PECGS case C083-000022 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/37cfbe65-b7f4-4c2b-a0aa-adc814b68b51

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 49 years; Year of birth: 1973; Education level: Vocational College or Some College.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Sigmoid colon; Age at diagnosis: 49.4 years (18,043 days); AJCC pathologic stage: Stage IIIB; Progression or recurrence: no.

Biospecimens (2 samples)
- Sample C083-000022_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000022_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
